Gene-level copy-number profile of tumor specimen ALCH-B2OM-TTP1-A from ALCHEMIST case ALCH-B2OM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,235 days).
Specimen ALCH-B2OM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 579f14d1-7754-4d45-acfc-94f1f21294b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2OM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/39f290f0-7fab-4ea5-955c-e1cf16831f16

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 3,253; copy number 2: 48,493; copy number 3: 5,835; copy number 4: 684; copy number 5: 64; copy number 6: 2; copy number 8: 1; copy number 10: 2; copy number 12: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,316,319–52,400,491, 2 genes: DNAH1, PPP2R5CP.
- chr3:52,777,595–52,835,729, 6 genes (within-gene range 0–2): ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr5:134,114,681–134,151,865, 1 gene (within-gene range 0–2): TCF7.
- chr7:98,211,439–98,252,232, 2 genes: BHLHA15, TECPR1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:128,787,253–128,829,794, 3 genes: TBC1D13, ENDOG, SPOUT1.
- chr15:25,199,448–25,250,940, 29 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:16,541,217–16,541,847, 1 gene: AC136619.2.
- chr16:28,494,643–28,512,051, 2 genes (within-gene range 0–2): APOBR, IL27.
- chr17:32,280,387–32,280,953, 1 gene (within-gene range 0–2): AC026620.1.
- chr22:29,705,256–29,770,413, 7 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 71 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,728,172, 62 genes, copy number 5 (broad region; genes not listed).
- chr17:83,135,734–83,240,804, 3 genes, copy number 5–8 (within-gene range 2–8): AC139099.2, AC139099.1, RPL23AP87.
- chr19:58,586,158–58,599,355, 2 genes, copy number 6: AC016629.1, AC016629.2.
- chr21:43,414,483–43,479,534, 4 genes, copy number 10–15: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 3,247. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
